Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8336, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8336-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

■■■■/o female with large right mass disease, for work up of abdominal pain. Imaging suggestive of renal vein tumor thrombus.

Specimens Submitted:

- 1: SP: Kidney, right, radical nephrectomy ■■■■
- 2: SP: Lymph node, paracaval/retrocaval, excision ■■■■
- 3: SP: Adrenal gland, right, adrenalectomy ■■■■
- 4: SP: Lymph node, interaortic-caval/pre-aortic, excision ■■■■
- 5: SP: Lymph node, para-aortic, excision ■■■■

DIAGNOSIS:

1. SP: Kidney, right, radical nephrectomy ■■■■

Tumor Type:

Renal cell carcinoma - Chromophobe type
with marked epithelial anaplastic features

Tumor Size:

Greatest diameter is 12 cm.

Local Invasion (for renal cortical types):

Tumor extensively replaces the region of the renal sinus/hilum and focally invading the proximal ureteral wall

Renal Vein Invasion:

Identified

Multiple other small to medium size vessels in the renal sinus also show invasion by tumor

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

-
2. SP: Lymph node, paracaval/retrocaval, excision ■■■■

Lymph Nodes:

[page 2 of 4]
ORIGINAL PATHOLOGIST REPORT

Number of nodes examined:15
Number of metastatic nodes:3
The largest metastatic node is 0.8cm
Perinodal (extracapsular) extension not identified

3. SP: Adrenal gland, right, adrenalectomy ():
Benign adrenal gland

4. SP: Lymph node, interaortic-caval/pre-aortic, excision ()
Lymph Nodes:
Number of nodes examined:7
Number of metastatic nodes:1
The largest metastatic node is 0.75cm
Perinodal (extracapsular) extension not identified

5. SP: Lymph node, para-aortic, excision ()
Lymph Nodes:
Not involved
Number of nodes examined:4

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	
	MIB-1 (Ki-67)	
	MIB-1 (Ki-67)	
	IMM RECUT	
	NEG CONT	
	IMM RECUT	
	NEG CONT	

Gross Description:

1). The specimen is received fresh, labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 761 g in total. The kidney measures 15 x 12 x 6 cm. The attached ureter measures 9 cm in length and 0.5 cm in diameter. The attached renal vein measures 1.2 cm in length and 1.5 cm in diameter. The vein is occluded by a soft tan mass. The renal ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a 12.0 x 11.5 x 5.0 cm multi lobular mass, obliterating the entire renal sinus, and abutting the capsule. The cut surface of the mass is tan yellow with area of hemorrhage and necrosis. Sections through the small remainder of the kidney, reveal a pink brown parenchyma. The cortex measures 0.7 cm and the calyces appear invaded by the tumor. Representative sections are submitted for TPS and for permanent sections. Photograph has been taken.

Summary of sections:

UVM -- ureteral and vessel margins
VT- renal vein and thrombus

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

T-- tumor
TC- tumor and capsule
TSF-- tumor with hilar fat
THF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections

2). The specimen is received in formalin, labeled "Paracaval/retrocaval lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.5 to 1.5 cm in greatest dimension. Representative sectioning of each lymph nodes are submitted.

Summary of sections:
LN -- lymph nodes

3). The specimen is received in formalin labeled, "Right adrenal gland" and consists of a resected adrenal gland measuring 2.9 x 1.6 x 0.6 cm and weighing 9 g after fixation. The specimen is serially sectioned to reveal a yellow tan fish flesh cut surface. Representative section are submitted.

Summary of sections:
A- adrenal gland

4). The specimen is received in formalin, labeled "Interaortic-caval lymph nodes and pre-aortic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.5 to 2.1 cm in greatest dimension. Representative sectioning of each lymph node is submitted.

Summary of sections:
LN -- lymph nodes

5). The specimen is received in formalin, labeled "Para-aortic nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 0.5 cm in greatest dimension. Representative sectioning of each lymph node is submitted.

Summary of sections:
LN -- lymph nodes

Summary of Sections:

Part 1: SP: Kidney, right, radical nephrectomy

Block	Sect. Site	PCs
2	rp	2
6	t	6
4	tc	4
2	thf	2
2	tk	2
2	tsf	2
1	uvm	1
1	vt	1

Part 2: SP: Lymph node, paracaval/retrocaval, excision

Block	Sect. Site	PCs
9	LN	10

Part 3: SP: Adrenal gland, right, adrenalectomy

Block	Sect. Site	PCs
6	A	6

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Part 4: SP: Lymph node, interaortic-caval/pre-aortic, excision

Block	Sect. Site	PCs
4	LN	7

Part 5: SP: Lymph node, para-aortic, excision

Block	Sect. Site	PCs
2	LN	2

Source: NCI Genomic Data Commons file 620fb2ad-73da-474b-baef-c585170d85eb (TCGA-KL-8336.3ED070A2-CC04-451C-B4A1-546CE3207427.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).